Somatic mutation profile of tumor specimen ALCH-B29R-TTP1-A (aliquot ALCH-B29R-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B29R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,852 days).
Specimen ALCH-B29R-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c140c41c-c5d0-4b7e-8fc3-3fd8eb9b34ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29R-NB1-A (Blood Derived Normal), aliquot ALCH-B29R-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb2046d5-16e2-421c-bafa-68a80364aa1d

The open-access MAF lists 456 somatic variants for this specimen: 322 protein-altering or splice-affecting, 81 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 81, Nonsense Mutation 28, Intron 25, Frame Shift Del 14, Splice Site 9, 5'UTR 9, RNA 7, Splice Region 7, 3'UTR 5, 3'Flank 5, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 37/162 reads (23%) | catalogued as rs193922329, CM012103; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 94/169 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 192/382 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778576631; called by muse, mutect2, varscan2
- ADAMTS6 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58682824; called by muse, mutect2, varscan2
- ADGRG4 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs375011333, COSV54965877; called by muse, mutect2, varscan2
- ADH4 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761301687, COSV55502594; called by muse, mutect2, varscan2
- AFF3 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as rs202104245, COSV57863774; called by muse, mutect2, varscan2
- AKAP9 | c.9298C>G p.Q3100E (on ENST00000359028; = p.Q3076E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100662551; called by muse, mutect2, varscan2
- ALDH7A1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs144671885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB3 | c.692G>T p.C231F (on ENST00000357560 / NM_133173.2; = p.C238F on NM_006051.3) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764762969, COSV100021204; called by muse, mutect2, varscan2
- ARHGAP36 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52269343; called by muse, mutect2, varscan2
- ARSJ | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59539858; called by muse, mutect2, varscan2
- ASXL3 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs868533580; called by muse, mutect2, varscan2
- BHMG1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs752648139; called by muse, mutect2, varscan2
- C10orf88 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV64404494; called by muse, mutect2, varscan2
- C16orf96 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs767812007; called by muse, mutect2, varscan2
- C4B | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 121/501 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs2734318; called by muse, mutect2, varscan2
- C4orf54 | c.4130A>G p.K1377R | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as rs1252644476; called by muse, mutect2, varscan2
- C4orf54 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs753181667; called by muse, mutect2
- CARMIL2 | c.1591+6G>A | Splice Region (SNP) | VAF 60/137 reads (44%) | catalogued as rs1197614404; called by muse, mutect2, varscan2
- CDH10 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV100050367; called by muse, mutect2, varscan2
- CDKN2A | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 491/640 reads (77%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as CX024722, COSV58694515, COSV58704405, COSV58722643; called by muse, mutect2, varscan2
- CENPE | c.5186A>G p.H1729R | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs924409014; called by muse, mutect2, varscan2
- CEP41 | c.757+3G>C | Splice Region (SNP) | VAF 114/381 reads (30%) | catalogued as COSV56219003; called by muse, mutect2, varscan2
- CHCHD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs777725979; called by muse, mutect2, varscan2
- CHI3L1 | c.539del p.A180Gfs*25 | Frame Shift Del (DEL) | VAF 106/296 reads (36%) | catalogued as COSV55139356; called by mutect2, pindel, varscan2
- COL16A1 | c.1257+1G>T p.X419_splice | Splice Site (SNP) | VAF 109/208 reads (52%) | catalogued as COSV54710296; called by muse, mutect2, varscan2
- COL1A2 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 302/714 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as COSV51963058, COSV51963070; called by muse, mutect2, varscan2
- CSMD3 | c.6313C>A p.P2105T (on ENST00000297405 / NM_001363185.1; = p.P2001T on NM_052900.3) | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234231; called by muse, mutect2, varscan2
- CST4 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1274607104, COSV54149770; called by muse, mutect2, varscan2
- CT55 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52278477; called by muse, mutect2, varscan2
- DACH1 | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.389); catalogued as COSV57512929; called by muse, mutect2, varscan2
- DGAT2L6 | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs996967355, COSV100284165, COSV60718210; called by muse, mutect2, varscan2
- EPHA10 | c.1070T>A p.L357Q | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1376618546; called by muse, mutect2, varscan2
- EPHA6 | c.1071C>A p.C357* | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | catalogued as COSV101064353; called by muse, varscan2
- ESRP1 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.53); catalogued as COSV64408780; called by muse, mutect2, varscan2
- ESYT2 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 115/383 reads (30%) | SIFT deleterious, low confidence (0); catalogued as rs1367761590; called by muse, mutect2, varscan2
- FAM135B | c.1356C>A p.S452R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52743093; called by muse, mutect2, varscan2
- FBXL7 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs769802991; called by muse, mutect2, varscan2
- FGFRL1 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV53260330; called by muse, mutect2, varscan2
- FMO2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs529847680; called by muse, mutect2, varscan2
- FRG2B | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101423510; called by muse, mutect2, varscan2
- GAL3ST3 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1442167460, COSV61748809; called by muse, mutect2, varscan2
- GIMAP6 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs148187154; called by muse, mutect2, varscan2
- GNGT2 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV55930316; called by muse, mutect2, varscan2
- GPAT3 | c.1206-1G>T p.X402_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100023332; called by muse, varscan2
- GPAT3 | c.1206G>T p.W402C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776142661; called by muse, varscan2
- GRIN3A | c.2830C>A p.L944M | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV62451932; called by muse, mutect2, varscan2
- GRM3 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV64467897; called by muse, mutect2, varscan2
- HECTD4 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.508); catalogued as rs757164325; called by muse, mutect2, varscan2
- HFM1 | c.2378C>A p.T793K | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647274; called by muse, mutect2, varscan2
- IGSF1 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100811762, COSV63836795; called by muse, mutect2, varscan2
- IRX1 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100116551; called by muse, mutect2, varscan2
- ITGA9 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 177/292 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs760149597; called by muse, mutect2, varscan2
- KEAP1 | c.613del p.E205Sfs*25 | Frame Shift Del (DEL) | VAF 35/75 reads (47%) | catalogued as COSV50671678; called by mutect2, pindel, varscan2
- KIF21A | c.3658A>T p.K1220* (on ENST00000361418 / NM_001378440.1; = p.K1207* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 103/319 reads (32%) | catalogued as COSV100735823; called by muse, mutect2, varscan2
- KMT2C | c.3590G>A p.R1197K | Missense Mutation (SNP) | VAF 69/370 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV51423884; called by muse, mutect2, varscan2
- KRTAP13-3 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs74823159, COSV100481828; called by muse, mutect2, varscan2
- MAST2 | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs753784078; called by muse, mutect2, varscan2
- MFAP5 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100848109, COSV63945004; called by muse, mutect2, varscan2
- MMP27 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs771350918; called by muse, mutect2, varscan2
- MROH5 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.017); catalogued as rs751731711, COSV71300632; called by muse, mutect2, varscan2
- MTCL1 | c.5487G>T p.E1829D (on ENST00000306329 / NM_001378206.1; = p.E1510D on NM_015210.4) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); catalogued as COSV100095519; called by muse, mutect2, varscan2
- MUC17 | c.3517G>T p.V1173F | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775923188; called by muse, mutect2, varscan2
- MYH8 | c.3127C>A p.Q1043K | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV101238623; called by muse, mutect2, varscan2
- MYO3A | c.3364G>T p.E1122* | Nonsense Mutation (SNP) | VAF 64/197 reads (32%) | catalogued as COSV56337575; called by muse, mutect2, varscan2
- MYOCD | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1270705368; called by muse, mutect2, varscan2
- NALCN | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV51963359; called by muse, mutect2, varscan2
- NBEAL1 | c.6523C>T p.R2175C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1287885838; called by muse, mutect2, varscan2
- NKRF | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1412039863; called by muse, mutect2, varscan2
- NRP2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1186838471, COSV55935827; called by muse, mutect2, varscan2
- NRXN3 | c.1317G>T p.K439N (on ENST00000335750 / NM_001330195.2; = p.K66N on NM_004796.6) | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs1019029084, COSV59755660; called by muse, mutect2
- NSMAF | c.1126-1G>T p.X376_splice | Splice Site (SNP) | VAF 88/179 reads (49%) | catalogued as rs765389027; called by muse, varscan2
- OBSCN | c.10762G>A p.G3588R | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778720702; called by muse, varscan2
- OPCML | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs145121891; called by muse, varscan2
- OR1D5 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs959448120; called by mutect2, varscan2
- OR4C16 | c.91C>A p.R31S | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs768595930, COSV58940480; called by muse, mutect2, varscan2
- OR5M10 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as COSV73242469; called by muse, varscan2
- OR8D2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1379045399, COSV100658935; called by muse, mutect2, varscan2
- OR8H2 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57944135, COSV99046876; called by muse, mutect2, varscan2
- OTOL1 | c.811A>T p.S271C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.386); catalogued as COSV100020282; called by muse, mutect2, varscan2
- PAPPA2 | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62804122; called by muse, mutect2, varscan2
- PARPBP | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs748632563, COSV59675515; called by muse, mutect2, varscan2
- PCDHB10 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 157/321 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186680451, COSV53376313; called by muse, mutect2, varscan2
- PDE3A | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV62975504; called by muse, mutect2, varscan2
- PHF21B | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1439479889; called by mutect2, varscan2
- PHKG1 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV99305079; called by muse, mutect2, varscan2
- PIEZO2 | c.6392G>T p.S2131I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV53292801; called by muse, mutect2, varscan2
- PLCL2 | c.1429G>T p.G477W (on ENST00000615277 / NM_001144382.2; = p.G351W on NM_015184.5) | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67624480; called by muse, varscan2
- PM20D1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV65648695; called by muse, mutect2, varscan2
- PVRIG | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs776800356, COSV99443853; called by muse, mutect2, varscan2
- RBMXL3 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs782408670, COSV57747838; called by muse, mutect2, varscan2
- RBP4 | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV65159897; called by muse, mutect2, varscan2
- RSF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs748850046, COSV100407151; called by muse, mutect2, varscan2
- RYR2 | c.13957-1G>T p.X4653_splice | Splice Site (SNP) | VAF 35/176 reads (20%) | catalogued as COSV63675752; called by muse, mutect2, varscan2
- SAXO1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 213/293 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101000043; called by muse, mutect2, varscan2
- SEC14L2 | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57242504; called by muse, mutect2, varscan2
- SFTPA2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100958794; called by muse, mutect2, varscan2
- SFTPB | c.869_871del p.G290del | In Frame Del (DEL) | VAF 92/430 reads (21%) | catalogued as rs944488327; called by mutect2, pindel, varscan2
- SI | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52284457; called by muse, mutect2, varscan2
- SLC2A9 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 154/500 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs779836250; called by muse, mutect2, varscan2
- SSTR3 | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142500, COSV60729408; called by muse, mutect2, varscan2
- ST18 | c.3043A>T p.T1015S | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104371892, COSV52488558; called by muse, mutect2, varscan2
- TAS2R60 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201185058, COSV60332390; called by muse, mutect2, varscan2
- THSD7B | c.1722C>A p.R574= | Splice Region (SNP) | VAF 31/82 reads (38%) | catalogued as rs762458222, COSV55698987; called by muse, mutect2, varscan2
- TPP1 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456959594; called by muse, mutect2, varscan2
- TRIM56 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755645354; called by muse, mutect2, varscan2
- TTN | c.85190C>T p.S28397L (on ENST00000591111; = p.S20973L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | PolyPhen benign (0.001); catalogued as rs1035231480, COSV60389705; called by muse, mutect2, varscan2
- UCP1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs752671873; called by muse, mutect2, varscan2
- UNC13A | c.2794C>A p.R932S | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV53208213; called by muse, mutect2, varscan2
- ZAP70 | c.1182C>A p.D394E | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53858096; called by muse, mutect2, varscan2
- ZFP42 | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1225794530, COSV58816348; called by muse, mutect2, varscan2
- ZMAT1 | c.1809T>G p.D603E | Missense Mutation (SNP) | VAF 191/430 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs772697728; called by muse, mutect2, varscan2
- ZSCAN10 | c.2086C>A p.P696T (on ENST00000252463; = p.P751T on NM_032805.3) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs897538463; called by muse, mutect2, varscan2
- A1CF | c.1610C>A p.A537D (on ENST00000373993 / NM_138932.2; = p.A529D on NM_014576.4) | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); called by muse, varscan2
- ABHD10 | c.892A>C p.I298L | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ACAT1 | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, varscan2
- ACTR8 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.182); called by muse, mutect2
- ADCY5 | c.1650G>T p.L550F | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AGA | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGA | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD13B | c.1826G>C p.R609P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKS1B | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1526T>A p.L509Q (on ENST00000409202 / NM_001007231.3; = p.L501Q on NM_014882.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP9 | c.1992G>T p.E664D (on ENST00000393797 / NM_001319850.2; = p.E645D on NM_032496.4) | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARL6IP4 | c.1226A>T p.D409V (on ENST00000315580 / NM_018694.3; = p.D390V on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMC6 | c.16T>A p.C6S | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AS3MT | c.719del p.N240Tfs*47 | Frame Shift Del (DEL) | VAF 84/241 reads (35%) | called by mutect2, pindel, varscan2
- ASB15 | c.1020C>A p.D340E | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, varscan2
- ASCL1 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- B4GALNT2 | c.1352A>T p.H451L | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BCORL1 | c.4970A>G p.Y1657C | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3328G>T p.E1110* | Nonsense Mutation (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- BRINP3 | c.1664T>C p.L555S | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BRWD3 | c.5093G>T p.G1698V | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- BRWD3 | c.4552C>A p.P1518T | Missense Mutation (SNP) | VAF 120/253 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- BRWD3 | c.2835+1G>T p.X945_splice | Splice Site (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- BTN3A1 | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D4 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CASR | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CBWD1 | c.514A>C p.K172Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC149 | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CD200R1L | c.70G>T p.G24* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | called by muse, varscan2
- CEP192 | c.5647A>T p.N1883Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHIT1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLEC4D | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNBD1 | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CNGA2 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 54/211 reads (26%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2359G>T p.G787* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- COASY | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL4A4 | c.3291G>T p.G1097= | Splice Region (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- CREB3L4 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.1102del p.A368Qfs*5 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by pindel, varscan2
- CSTF2T | c.1339G>C p.G447R | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CTC1 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DBX2 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF12L2 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DENND2C | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DENND4B | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 113/535 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- DEPDC5 | c.1871-5C>T | Splice Region (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- DIAPH3 | c.1480G>T p.D494Y (on ENST00000400324 / NM_001042517.2; = p.D231Y on NM_030932.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DMBT1 | c.5797A>G p.I1933V (on ENST00000338354 / NM_001377530.1; = p.I1176V on NM_004406.3) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- DNAH9 | c.5405A>T p.Q1802L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DSG1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ERCC6L | c.2671C>A p.R891S | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120A | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM207A | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAT1 | c.13003A>T p.K4335* | Nonsense Mutation (SNP) | VAF 67/124 reads (54%) | called by muse, mutect2, varscan2
- FBRSL1 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG | c.6262_6263delinsT p.G2088Cfs*7 | Frame Shift Del (DEL) | VAF 76/318 reads (24%) | called by pindel, varscan2*
- FLT3LG | c.78del p.T27Pfs*75 | Frame Shift Del (DEL) | VAF 83/203 reads (41%) | called by mutect2, pindel, varscan2
- FMO4 | c.712A>T p.R238* | Nonsense Mutation (SNP) | VAF 59/324 reads (18%) | called by muse, mutect2, varscan2
- FRG2C | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, varscan2
- FSHR | c.1551C>A p.C517* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- GAD2 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GASK1B | c.1316A>G p.D439G | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GCNT7 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GIMAP8 | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRB | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNB1L | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 92/443 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPATCH8 | c.2981G>T p.R994L | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GTDC1 | c.1174G>T p.D392Y (on ENST00000344850 / NM_001354361.1; = p.D307Y on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); called by muse, varscan2
- GTF2IRD2B | c.571+8A>T | Splice Region (SNP) | VAF 84/506 reads (17%) | called by muse, varscan2
- H2BW1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 52/486 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAVCR2 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HERC4 | c.2333A>G p.D778G (on ENST00000395198 / NM_022079.3; = p.D770G on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- HOXA9 | c.176A>T p.K59M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IBA57 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.048); called by muse, mutect2
- IGSF1 | c.2399C>A p.S800Y | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- IGSF1 | c.2378C>A p.A793D | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.172); called by muse, varscan2
- IL1RAPL2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- IL1RAPL2 | c.985T>A p.Y329N | Missense Mutation (SNP) | VAF 136/272 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL22 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, varscan2
- ISY1-RAB43 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ITPKC | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ITPR2 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANSL2 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KBTBD13 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 197/349 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNA2 | c.287del p.G96Afs*3 | Frame Shift Del (DEL) | VAF 64/280 reads (23%) | called by mutect2, pindel, varscan2
- KCNT2 | c.3126C>A p.N1042K | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KDR | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 51/175 reads (29%) | called by muse, mutect2, varscan2
- KIAA2012 | c.916G>C p.G306R | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KIF26B | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL1 | c.1592A>G p.K531R | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- LAMB4 | c.4426G>T p.E1476* | Nonsense Mutation (SNP) | VAF 122/294 reads (41%) | called by muse, mutect2, varscan2
- LILRB2 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPAR3 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, varscan2
- LRCH2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN1 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 96/145 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRFN5 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 136/380 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MACF1 | c.9490A>G p.K3164E | Missense Mutation (SNP) | VAF 64/128 reads (50%) | called by muse, mutect2, varscan2
- MAGEB18 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGI3 | c.1999-1G>C p.X667_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | called by muse, varscan2
- MCF2L2 | c.2567G>T p.R856L | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MICAL3 | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 54/106 reads (51%) | called by muse, varscan2
- MMRN1 | c.3552T>A p.D1184E | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- MS4A1 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 160/469 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A8 | c.149del p.P50Hfs*8 | Frame Shift Del (DEL) | VAF 97/400 reads (24%) | called by mutect2, pindel, varscan2
- MUC16 | c.35843C>A p.S11948* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- MUC16 | c.10468T>C p.S3490P | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MUC22 | c.3350C>T p.T1117I | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.15); called by muse, mutect2, varscan2
- MUC7 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 168/503 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NAALADL2 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NBEAL1 | c.467G>C p.C156S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEURL1 | c.821del p.P274Rfs*230 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- NEUROD4 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- NOD2 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOD2 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- NRXN3 | c.1319G>T p.C440F (on ENST00000335750 / NM_001330195.2; = p.C67F on NM_004796.6) | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- OLFM2 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OMG | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, varscan2
- OPLAH | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- OR10A2 | c.16del p.L6Cfs*11 | Frame Shift Del (DEL) | VAF 30/63 reads (48%) | called by mutect2, pindel, varscan2
- OR1C1 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OR1E1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5AR1 | c.616A>C p.I206L | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.301); called by muse, varscan2
- OXCT1 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PA2G4 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PCCA | c.137T>A p.M46K | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCCA | c.1285-1G>T p.X429_splice | Splice Site (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 95/154 reads (62%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHA7 | c.530_545del p.Y177Cfs*8 | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | called by mutect2, varscan2
- PCYOX1L | c.1461G>T p.M487I | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZRN4 | c.1624del p.A542Qfs*14 (on ENST00000402685 / NM_001164595.2; = p.A284Qfs*14 on NM_013377.4) | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- PEX19 | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PIAS2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1 | c.9880G>T p.A3294S | Missense Mutation (SNP) | VAF 192/603 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.4337C>G p.T1446S | Missense Mutation (SNP) | VAF 183/624 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLA2G4A | c.1622A>G p.K541R | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLP1 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 172/744 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PLXNA3 | c.4202C>A p.P1401H | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); called by muse, varscan2
- PPP1R16B | c.899-1G>T p.X300_splice | Splice Site (SNP) | VAF 39/105 reads (37%) | called by muse, mutect2, varscan2
- PRKCQ | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRR12 | c.1434C>G p.Y478* (on ENST00000615927; = p.Y1299* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- PRR16 | c.317_325del p.P106_A108del (on ENST00000407149 / NM_001300783.2; = p.P83_A85del on NM_016644.2) | In Frame Del (DEL) | VAF 41/111 reads (37%) | called by pindel, varscan2
- PRR32 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 219/440 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTPRD | c.618_620delinsTGT p.E206_C207delinsDV | Missense Mutation (TNP) | VAF 13/136 reads (10%) | called by muse*, pindel, varscan2*
- PXDN | c.4370C>A p.A1457D | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RAB27A | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 139/244 reads (57%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBX1 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RGS12 | c.3783G>A p.W1261* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- RNF175 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RP1 | c.2841T>A p.C947* | Nonsense Mutation (SNP) | VAF 105/242 reads (43%) | called by muse, mutect2, varscan2
- RTL6 | c.64A>G p.M22V | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTN1 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 119/485 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SCAF4 | c.2480C>G p.S827* | Nonsense Mutation (SNP) | VAF 72/180 reads (40%) | called by muse, varscan2
- SCX | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SEC14L2 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SEC22C | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- SERPINA11 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SH3PXD2A | c.1987C>T p.P663S (on ENST00000369774 / NM_001365079.1; = p.P635S on NM_014631.2) | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SI | c.3981T>A p.N1327K | Missense Mutation (SNP) | VAF 139/227 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0.232); called by muse, varscan2
- SLC28A3 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SLC2A14 | c.1362C>A p.Y454* | Nonsense Mutation (SNP) | VAF 54/157 reads (34%) | called by muse, mutect2, varscan2
- SLC4A4 | c.691G>A p.V231I (on ENST00000264485 / NM_001098484.3; = p.V187I on NM_003759.4) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SLC5A8 | c.1539_1542del p.M513Ifs*18 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by pindel, varscan2
- SLIT3 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SNX11 | c.129+1G>T p.X43_splice | Splice Site (SNP) | VAF 24/120 reads (20%) | called by muse, varscan2
- SNX9 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SPANXN1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 74/315 reads (23%) | called by muse, mutect2, varscan2
- SPATA1 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.337); called by muse, varscan2
- SPATA19 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SPINK2 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ST6GAL1 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 77/197 reads (39%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 66/238 reads (28%) | called by muse, varscan2
- STRC | c.4374A>T p.P1458= | Splice Region (SNP) | VAF 73/150 reads (49%) | called by muse, mutect2, varscan2
- SVIL | c.2125G>A p.D709N (on ENST00000355867 / NM_021738.3; = p.D315N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TAS2R50 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TBC1D4 | c.1436T>A p.V479E | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TENM3 | c.4421C>A p.P1474Q | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TFR2 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 200/458 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TIAM1 | c.3161C>T p.T1054I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLL1 | c.1148C>A p.P383Q | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TLL2 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, varscan2
- TMEM132C | c.1084G>C p.V362L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TMEM132D | c.2051dup p.G685Rfs*33 | Frame Shift Ins (INS) | VAF 26/162 reads (16%) | called by pindel, varscan2
- TNKS | c.3351del p.E1117Dfs*42 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- TNR | c.4037G>T p.R1346L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TPSB2 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.662); called by muse, mutect2
- TPTE | c.1021G>T p.G341C (on ENST00000618007 / NM_199261.4; = p.G323C on NM_199259.4) | Missense Mutation (SNP) | VAF 30/407 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM42 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 125/187 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM43B | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM50 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TRIO | c.4934C>A p.S1645Y | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TRIO | c.5336G>T p.S1779I | Missense Mutation (SNP) | VAF 136/383 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSHZ3 | c.2908G>A p.D970N | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTLL1 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTLL8 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- TUBAL3 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC16 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VPS13A | c.680A>T p.D227V | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- WBP4 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | called by muse, varscan2
- XPNPEP2 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF236 | c.2615A>C p.Q872P | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF394 | c.1463A>G p.H488R | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF423 | c.1332G>T p.K444N (on ENST00000563137 / NM_001379286.1; = p.K436N on NM_015069.4) | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZNF655 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF711 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF775 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZWINT | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZYX | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- AGBL4 | c.1350C>T p.P450= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- AMER3 | c.2565C>A p.A855= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- C12orf40 | c.1689A>T p.T563= | Silent (SNP) | VAF 104/311 reads (33%) | catalogued as COSV61131901; called by muse, mutect2, varscan2
- CCDC168 | c.19413A>T p.L6471= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- CCDC168 | c.6418C>A p.R2140= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- CCN3 | c.927C>A p.I309= | Silent (SNP) | VAF 95/323 reads (29%) | catalogued as rs749384957; called by muse, mutect2, varscan2
- CENPF | c.648G>T p.V216= | Silent (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- CEP350 | c.1311G>T p.L437= | Silent (SNP) | VAF 88/256 reads (34%) | called by muse, mutect2, varscan2
- CFHR5 | c.867T>C p.H289= | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, varscan2
- CHST8 | c.690C>T p.G230= | Silent (SNP) | VAF 72/140 reads (51%) | called by muse, mutect2, varscan2
- CNGA2 | c.183G>A p.Q61= | Silent (SNP) | VAF 54/211 reads (26%) | catalogued as rs1482701161; called by muse, mutect2, varscan2
- DDX23 | c.2220T>C p.D740= | Silent (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- DNAJC25 | c.51G>T p.R17= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- DSG4 | c.2700G>C p.V900= | Silent (SNP) | VAF 87/168 reads (52%) | called by muse, varscan2
- EBF2 | c.1170C>A p.I390= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV68776733; called by muse, mutect2, varscan2
- FAM102A | c.319C>T p.L107= | Silent (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- FAM25C | c.189G>A p.K63= | Silent (SNP) | VAF 71/285 reads (25%) | called by muse, mutect2, varscan2
- FGD5 | c.1725G>A p.R575= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs757020255, COSV53251170; called by muse, mutect2, varscan2
- FSD2 | c.1512G>A p.E504= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- GAB4 | c.78C>T p.P26= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as rs757242657; called by muse, mutect2, varscan2
- GABRA2 | c.852G>T p.V284= | Silent (SNP) | VAF 70/283 reads (25%) | called by muse, varscan2
- GALNT14 | c.1455C>T p.G485= | Silent (SNP) | VAF 75/184 reads (41%) | catalogued as rs377741520; called by muse, mutect2, varscan2
- GCGR | c.1077C>A p.G359= | Silent (SNP) | VAF 84/270 reads (31%) | called by muse, mutect2
- GIPC2 | c.327C>T p.A109= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1359529541; called by muse, mutect2, varscan2
- GRIN2B | c.3414A>T p.R1138= | Silent (SNP) | VAF 50/356 reads (14%) | catalogued as COSV74205537; called by muse, mutect2, varscan2
- GRK5 | c.681G>T p.G227= | Silent (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- GSG1L2 | c.738G>A p.R246= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as rs1369943871; called by muse, varscan2
- HECW1 | c.24G>A p.V8= | Silent (SNP) | VAF 54/274 reads (20%) | catalogued as COSV67843019; called by muse, mutect2, varscan2
- IKZF1 | c.1311G>C p.L437= | Silent (SNP) | VAF 113/276 reads (41%) | called by muse, mutect2, varscan2
- IL9R | c.126C>T p.V42= | Silent (SNP) | VAF 16/385 reads (4%) | catalogued as rs1411758101, COSV54901225; called by muse, mutect2
- ITGAD | c.414C>T p.P138= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as rs745333401; called by muse, mutect2, varscan2
- JAKMIP1 | c.267G>A p.E89= | Silent (SNP) | VAF 113/304 reads (37%) | catalogued as rs1181491262; called by muse, mutect2, varscan2
- KCNU1 | c.1020C>T p.I340= | Silent (SNP) | VAF 11/111 reads (10%) | called by muse, varscan2
- KCNU1 | c.2247G>A p.K749= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs750016225, COSV67760308; called by muse, mutect2, varscan2
- KIF21A | c.2463G>T p.V821= (on ENST00000361418 / NM_001378440.1; = p.V808= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 163/510 reads (32%) | called by muse, mutect2, varscan2
- KLHL32 | c.354G>T p.A118= | Silent (SNP) | VAF 80/154 reads (52%) | catalogued as rs138548618, COSV100987111; called by muse, mutect2, varscan2
- KLHL35 | c.786G>A p.L262= | Silent (SNP) | VAF 106/450 reads (24%) | called by muse, mutect2, varscan2
- LGR6 | c.2532C>T p.R844= (on ENST00000367278 / NM_001017403.1; = p.R792= on NM_021636.3) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs768029439, COSV55158047; called by muse, mutect2, varscan2
- LPL | c.198C>A p.T66= | Silent (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- LPP | c.1635A>T p.P545= | Silent (SNP) | VAF 83/234 reads (35%) | called by muse, mutect2, varscan2
- LTC4S | c.300C>T p.S100= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs1440483784; called by muse, mutect2
- MKRN3 | c.1497G>T p.L499= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- MUC12 | c.10287T>A p.S3429= (on ENST00000379442; = p.S3286= on NM_001164462.1) | Silent (SNP) | VAF 133/3581 reads (4%) | called by muse, mutect2
- MUS81 | c.1455G>C p.V485= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- MYH7B | c.1017A>C p.P339= | Silent (SNP) | VAF 71/230 reads (31%) | called by muse, mutect2, varscan2
- NCKAP5L | c.2691G>T p.R897= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2
- NEB | c.10836C>G p.V3612= | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- NFIA | c.1446C>G p.P482= | Silent (SNP) | VAF 74/207 reads (36%) | catalogued as rs1286660443, COSV63607944; called by muse, mutect2, varscan2
- NPSR1 | c.1062G>T p.R354= | Silent (SNP) | VAF 43/199 reads (22%) | catalogued as COSV100706170; called by muse, varscan2
- OAS3 | c.1839G>T p.A613= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV57445251; called by muse, mutect2, varscan2
- PDAP1 | c.252G>A p.E84= | Silent (SNP) | VAF 107/252 reads (42%) | called by muse, mutect2, varscan2
- PDILT | c.597A>T p.P199= | Silent (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- PHKB | c.15G>A p.A5= | Silent (SNP) | VAF 91/253 reads (36%) | catalogued as rs925799294; called by muse, mutect2, varscan2
- PRKDC | c.10353G>A p.L3451= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, varscan2
- PRR33 | c.60C>G p.T20= | Silent (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- RELN | c.4401T>A p.G1467= | Silent (SNP) | VAF 163/663 reads (25%) | called by muse, mutect2, varscan2
- RFPL2 | c.675C>T p.D225= | Silent (SNP) | VAF 85/233 reads (36%) | catalogued as rs763461838, COSV50715209; called by muse, mutect2, varscan2
- ROBO1 | c.978T>G p.G326= | Silent (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- RTL9 | c.1707C>A p.A569= | Silent (SNP) | VAF 194/402 reads (48%) | called by muse, varscan2
- RYR2 | c.4302T>C p.P1434= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SGCZ | c.27T>A p.I9= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV101170169; called by muse, mutect2, varscan2
- SLC16A2 | c.1215C>A p.P405= | Silent (SNP) | VAF 90/193 reads (47%) | catalogued as COSV99330258; called by muse, mutect2, varscan2
- SLC1A2 | c.591T>A p.V197= | Silent (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1092C>T p.L364= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs781373267; called by muse, mutect2, varscan2
- SLITRK5 | c.267C>A p.S89= | Silent (SNP) | VAF 64/235 reads (27%) | catalogued as rs866618278, COSV61522758, COSV61523823; called by muse, varscan2
- SMIM23 | c.231T>G p.L77= | Silent (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- SMPD3 | c.981C>A p.A327= | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- SNX4 | c.168G>A p.K56= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs773765068; called by muse, mutect2
- THSD7B | c.4710C>A p.I1570= (on ENST00000272643; = p.I1568= on NM_001316349.2) | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as COSV55716924; called by muse, varscan2
- TRANK1 | c.1395G>A p.E465= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs552432748; called by muse, mutect2, varscan2
- TTLL13P | c.775C>A p.R259= | Silent (SNP) | VAF 36/82 reads (44%) | called by muse, varscan2
- TTLL8 | c.1113G>A p.E371= | Silent (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- UNC13C | c.4647C>T p.C1549= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs1294671839; called by muse, mutect2, varscan2
- USP17L1 | c.579C>T p.I193= | Silent (SNP) | VAF 138/344 reads (40%) | called by muse, mutect2, varscan2
- VWC2 | c.138G>A p.E46= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as rs749075269; called by muse, mutect2, varscan2
- ZEB2 | c.459G>A p.L153= | Silent (SNP) | VAF 26/108 reads (24%) | called by muse, varscan2
- ZNF18 | c.519G>T p.G173= | Silent (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- ZNF284 | c.6C>T p.T2= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs756550819; called by muse, mutect2, varscan2
- ZNF804A | c.1980C>T p.P660= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ZNF804B | c.2379T>C p.N793= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as rs1445890128; called by muse, mutect2, varscan2
- ZXDB | c.1674C>T p.F558= | Silent (SNP) | VAF 55/584 reads (9%) | called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288252C>A | Intron (SNP) | VAF 85/292 reads (29%) | called by muse, mutect2, varscan2
- AC112695.1 | n.291G>T | RNA (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- ACTR3B | c.-77G>T | 5'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ARAP1 | c.*19G>A | 3'UTR (SNP) | VAF 135/354 reads (38%) | called by muse, mutect2, varscan2
- ATP11B | c.3318+7076C>T | Intron (SNP) | VAF 96/262 reads (37%) | called by muse, varscan2
- BLOC1S5-TXNDC5 | c.372+39102G>A | Intron (SNP) | VAF 40/201 reads (20%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701015 C>A | 3'Flank (SNP) | VAF 79/153 reads (52%) | called by muse, mutect2, varscan2
- CAPS2 | c.1670-2687G>T | Intron (SNP) | VAF 28/71 reads (39%) | catalogued as rs1176165535, COSV100157458; called by muse, mutect2, varscan2
- CARS1 | c.-15C>T | 5'UTR (SNP) | VAF 64/114 reads (56%) | catalogued as rs1000200315; called by muse, mutect2, varscan2
- CCT7 | c.-32dup | 5'UTR (INS) | VAF 47/125 reads (38%) | called by mutect2, pindel, varscan2
- CGREF1 | chr2:27099794 G>A | 3'Flank (SNP) | VAF 95/450 reads (21%) | catalogued as rs768046251, COSV53149873; called by muse, mutect2, varscan2
- CHRD | c.-4C>A | 5'UTR (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1729G>T | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- COG6 | chr13:39655631 C>A | 5'Flank (SNP) | VAF 74/269 reads (28%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11762G>T | Intron (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- DCAF7 | c.*65+42T>G | Intron (SNP) | VAF 48/147 reads (33%) | catalogued as rs922952271; called by muse, mutect2, varscan2
- DCN | c.211+5526C>T | Intron (SNP) | VAF 28/104 reads (27%) | called by muse, varscan2
- DYNLRB1 | c.79+3585G>T | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- EGFR | c.3271+49A>G | Intron (SNP) | VAF 74/188 reads (39%) | called by muse, mutect2, varscan2
- FAM3A | c.152-15G>C | Intron (SNP) | VAF 172/347 reads (50%) | called by muse, mutect2, varscan2
- FOXL2 | c.*24A>G | 3'UTR (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- FXYD2 | c.25+18C>A | Intron (SNP) | VAF 95/330 reads (29%) | called by muse, mutect2, varscan2
- GFPT2 | c.7+523G>T | Intron (SNP) | VAF 68/188 reads (36%) | called by muse, mutect2, varscan2
- GLB1L3 | c.-75G>T | 5'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2
- GUSBP10 | n.58G>A | RNA (SNP) | VAF 37/87 reads (43%) | catalogued as rs1466251375; called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1263C>T | Intron (SNP) | VAF 52/217 reads (24%) | called by muse, mutect2, varscan2
- HNF1A | c.1501+17C>A | Intron (SNP) | VAF 134/313 reads (43%) | catalogued as COSV99982539, COSV99983084; called by muse, mutect2, varscan2
- INSL6 | c.*5C>T | 3'UTR (SNP) | VAF 65/89 reads (73%) | catalogued as rs371039712; called by muse, mutect2, varscan2
- KCNC1 | chr11:17779536 G>A | 3'Flank (SNP) | VAF 50/159 reads (31%) | catalogued as rs927483438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+1030G>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- KLK12 | c.37+56C>A | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2
- LINC01036 | n.202C>A | RNA (SNP) | VAF 82/177 reads (46%) | called by muse, mutect2, varscan2
- LYPD3 | c.382+137G>T | Intron (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- MIF | chr22:23895830 A>C | 3'Flank (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21495823 G>C | 3'Flank (SNP) | VAF 22/48 reads (46%) | called by mutect2, varscan2
- MIR518A2 | n.13G>C | RNA (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- MIR663B | n.112T>C | RNA (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1669+1486A>C | Intron (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- OBSCN | c.6755-97C>T | Intron (SNP) | VAF 31/118 reads (26%) | catalogued as rs747944570; called by muse, mutect2
- OTOAP1 | n.2208C>A | RNA (SNP) | VAF 32/299 reads (11%) | called by muse, mutect2, varscan2
- PGA5 | c.657-148G>C | Intron (SNP) | VAF 71/229 reads (31%) | called by muse, mutect2, varscan2
- PSEN2 | c.*29T>C | 3'UTR (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- PTPRN2 | c.113-42964T>A | Intron (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- RPL10 | c.-112G>T | 5'UTR (SNP) | VAF 306/609 reads (50%) | called by muse, mutect2
- SLAIN1 | c.-3A>G | 5'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, varscan2
- STMN4 | c.510+733G>T | Intron (SNP) | VAF 34/114 reads (30%) | called by muse, varscan2
- TAF3 | c.-19G>T | 5'UTR (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- TBX20 | c.-36G>T | 5'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- TLCD3B | chr16:30035460 C>A | 5'Flank (SNP) | VAF 48/112 reads (43%) | called by muse, varscan2
- TPST2 | c.-160-10625G>T | Intron (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2
- TSHR | c.692+161C>A | Intron (SNP) | VAF 81/147 reads (55%) | catalogued as COSV53331256; called by muse, mutect2, varscan2
- VPS8 | c.447+1524T>G | Intron (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- XIST | n.8835C>A | RNA (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
